Somatic mutation profile of tumor specimen TCGA-DH-5143-01A (aliquot TCGA-DH-5143-01A-01D-1468-08) from TCGA case TCGA-DH-5143, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.9 years (11,291 days).
Specimen TCGA-DH-5143-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de5bc600-6b8a-4660-9bc3-21161cbdfeb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-5143-10A (Blood Derived Normal), aliquot TCGA-DH-5143-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89092c36-4ac0-4661-b01d-0dfbe3aac4ab

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Silent 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 48/151 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 48/92 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACACA | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 101/409 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs770987352; called by muse, mutect2, varscan2
- ADAMTS5 | c.1199A>G p.D400G | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395577458, COSV53175534; called by muse, mutect2
- CALR | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1315949624, COSV57117476; called by muse, mutect2, varscan2
- CFAP410 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs757262220, COSV100297124; called by mutect2, varscan2
- COCH | c.610T>C p.S204P (on ENST00000216361 / NM_001347720.1; = p.S139P on NM_004086.3) | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV53549685; called by muse, mutect2, varscan2
- EPHA4 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 105/728 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV56026243; called by muse, mutect2, varscan2
- EXOC2 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV57861095; called by muse, mutect2, varscan2
- F5 | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 48/371 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV63120377; called by muse, mutect2, varscan2
- HNRNPL | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55491069; called by muse, mutect2
- HOXD4 | c.612C>A p.N204K | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60459287; called by muse, mutect2, varscan2
- MID2 | c.470G>A p.C157Y | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53306779; called by muse, mutect2, varscan2
- NAT10 | c.1298A>C p.Q433P | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV57662337; called by muse, mutect2, varscan2
- RYR3 | c.12067T>C p.Y4023H (on ENST00000389232; = p.Y4024H on NM_001036.6) | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66777504; called by muse, mutect2, varscan2
- SPAG17 | c.5911A>G p.S1971G | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV60452705; called by muse, mutect2, varscan2
- SPIRE1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475654330, COSV100563779, COSV59152151; called by muse, mutect2, varscan2
- TBX15 | c.1079C>T p.S360L (on ENST00000369429 / NM_001330677.2; = p.S254L on NM_152380.3) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); catalogued as rs1313804216, COSV52867418; called by muse, mutect2, varscan2
- TRABD | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as rs375342223, COSV100327007; called by muse, mutect2, varscan2
- VMP1 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as COSV51864572; called by muse, mutect2, varscan2
- NDUFV2 | c.698_714del p.S233* | Frame Shift Del (DEL) | VAF 22/268 reads (8%) | called by mutect2, pindel
- YLPM1 | c.1413_1414del p.H471Qfs*8 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- A2M | c.2289C>T p.T763= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as rs753034102, COSV59382818; called by muse, mutect2, varscan2
- FOXJ2 | c.852G>A p.S284= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as rs748494119, COSV50817457; called by muse, mutect2
- PZP | c.2307C>T p.T769= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as rs773178421, COSV54354312; called by muse, mutect2
